Gene-level copy-number profile of tumor specimen TCGA-IW-A3M6-01A from TCGA case TCGA-IW-A3M6, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 59.3 years (21,674 days).
Specimen TCGA-IW-A3M6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.f72d24bd-65f1-4b7e-b2e4-4e93cf4023f2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IW-A3M6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8a1a3086-45f6-4328-ac7e-7b99ce045866

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 75; copy number 1: 3; copy number 2: 17,658; copy number 3: 7,909; copy number 4: 30,513; copy number 6: 1,734; copy number 7: 1,897; copy number 8: 23; copy number 9: 2; copy number 10: 2; copy number 11: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IW-A3M6-01A-11D-A21P-01): tumor purity 0.75, ploidy 1.72, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 75 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:50,846,468–50,974,634, 2 genes: MRPS6P2, CDKN2C.
- chr7:152,366,763–152,402,893, 4 genes: AC104692.2, AC104692.1, SEPTIN7P6, Y_RNA.
- chr9:14,475–4,679,502, 62 genes (broad region; genes not listed).
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,929,457–21,995,301, 3 genes: ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:78,437,850–78,599,406, 2 genes, copy number 10: AC064872.1, AC092660.1.
- chr2:170,178,145–170,655,171, 2 genes, copy number 9 (within-gene range 6–9): MYO3B, MYO3B-AS1.
- chr2:190,189,735–190,509,205, 4 genes, copy number 11 (within-gene range 8–11): HIBCH, INPP1, MFSD6, AC093388.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
